Somatic mutation profile of cancer-model specimen HCM-BROD-0132-C25-85A (3D Organoid, passage 10; aliquot HCM-BROD-0132-C25-85A-01D-A79C-36), derived from the metastatic tumor of HCMI case HCM-BROD-0132-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 73.1 years (26,698 days).
Specimen HCM-BROD-0132-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6edaba5b-0c7c-46c0-b4fb-0971ff73111b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0132-C25-10B (Blood Derived Normal), aliquot HCM-BROD-0132-C25-10B-01D-A79C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/21abbdd9-cf87-4bba-8a41-fd537de3735d

The open-access MAF lists 388 somatic variants for this specimen: 280 protein-altering or splice-affecting, 95 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 243, Silent 95, Nonsense Mutation 13, Frame Shift Del 10, Intron 6, Frame Shift Ins 6, Splice Site 3, 5'UTR 2, Splice Region 2, 3'Flank 2, Translation Start Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERCC2 | c.713A>G p.N238S | Missense Mutation (SNP) | VAF 253/406 reads (62%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55538701; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 201/204 reads (99%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.85G>C p.D29H | Missense Mutation (SNP) | VAF 78/270 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519920, COSV67960002, COSV67960389, COSV67960852; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ZEB2 | c.3046C>T p.R1016* | Nonsense Mutation (SNP) | VAF 190/269 reads (71%) | catalogued as rs886041989; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADGRL1 | c.1940C>T p.T647M (on ENST00000340736 / NM_001008701.3; = p.T642M on NM_014921.5) | Missense Mutation (SNP) | VAF 262/736 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs200128522; called by muse, mutect2, varscan2
- AHNAK | c.4826A>G p.K1609R | Missense Mutation (SNP) | VAF 84/283 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.169); catalogued as rs1191562242; called by muse, mutect2, varscan2
- ALCAM | c.878G>A p.R293K | Missense Mutation (SNP) | VAF 86/307 reads (28%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.866); catalogued as rs763413418; called by muse, mutect2, varscan2
- ARL13B | c.929A>C p.K310T (on ENST00000394222 / NM_001174150.2; = p.K203T on NM_144996.4) | Missense Mutation (SNP) | VAF 75/316 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV57396574; called by muse, mutect2, varscan2
- ATP13A2 | c.2635G>A p.G879S | Missense Mutation (SNP) | VAF 150/442 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs771014262, COSV58700403, COSV58701431; called by muse, mutect2, varscan2
- ATP1A3 | c.412G>A p.V138M (on ENST00000545399 / NM_001256214.2; = p.V125M on NM_152296.5) | Missense Mutation (SNP) | VAF 69/194 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV57486087; called by muse, mutect2, varscan2
- ATP2B3 | c.3481G>A p.D1161N | Missense Mutation (SNP) | VAF 245/925 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.509); catalogued as rs782400729, COSV99684561; called by muse, mutect2, varscan2
- AVEN | c.753C>A p.C251* | Nonsense Mutation (SNP) | VAF 124/510 reads (24%) | catalogued as rs370527932; called by muse, mutect2, varscan2
- CDC42EP1 | c.84G>T p.Q28H | Missense Mutation (SNP) | VAF 303/442 reads (69%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as rs754729269; called by muse, mutect2, varscan2
- CLCN4 | c.1535C>T p.T512M | Missense Mutation (SNP) | VAF 360/658 reads (55%) | SIFT tolerated (0.15); PolyPhen benign (0.427); catalogued as rs1477351576; called by muse, mutect2, varscan2
- CTCF | c.1650C>G p.F550L | Missense Mutation (SNP) | VAF 61/375 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV50470300; called by muse, mutect2, varscan2
- CX3CL1 | c.200C>T p.T67M | Missense Mutation (SNP) | VAF 182/216 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773504821, COSV50055921, COSV99136451; called by muse, mutect2, varscan2
- CYP1A2 | c.1447G>A p.V483M | Missense Mutation (SNP) | VAF 188/520 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.876); catalogued as rs143028942; called by muse, mutect2, varscan2
- DACH2 | c.1795G>T p.A599S | Missense Mutation (SNP) | VAF 26/230 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV100914119; called by mutect2, varscan2
- DCDC2 | c.978A>C p.E326D | Missense Mutation (SNP) | VAF 152/324 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs1408902119; called by muse, mutect2, varscan2
- DCN | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 150/233 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778750338, COSV50006318; called by muse, mutect2, varscan2
- DMRTA2 | c.145G>A p.G49S | Missense Mutation (SNP) | VAF 20/780 reads (3%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0.011); catalogued as rs1339501309; called by muse, mutect2
- DNAH1 | c.7949A>G p.N2650S | Missense Mutation (SNP) | VAF 9/165 reads (5%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as rs1417452896; called by muse, mutect2
- DNAH11 | c.13273G>A p.G4425S | Missense Mutation (SNP) | VAF 113/442 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60944571; called by muse, mutect2, varscan2
- DNM1L | c.967G>A p.G323S | Missense Mutation (SNP) | VAF 103/230 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99846127; called by muse, mutect2, varscan2
- EBF3 | c.673G>A p.V225M | Missense Mutation (SNP) | VAF 397/595 reads (67%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.699); catalogued as rs913603139, COSV62471534; called by muse, mutect2, varscan2
- EFR3B | c.2104G>T p.V702L | Missense Mutation (SNP) | VAF 183/587 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs1406452118; called by muse, mutect2
- ELOA3 | c.941G>A p.R314H | Missense Mutation (SNP) | VAF 163/1175 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as rs773973113, COSV99796167; called by muse, mutect2, varscan2
- FAT2 | c.8066C>G p.P2689R | Missense Mutation (SNP) | VAF 103/310 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55820224; called by muse, mutect2, varscan2
- FLNC | c.3322G>A p.E1108K | Missense Mutation (SNP) | VAF 254/462 reads (55%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as rs781352216; called by muse, varscan2
- GAMT | c.299G>A p.R100Q | Missense Mutation (SNP) | VAF 129/485 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs754770522, COSV99282563; called by muse, mutect2, varscan2
- GDPD5 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 114/272 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.261); catalogued as rs778484378, COSV100409284; called by muse, mutect2, varscan2
- GLYATL3 | c.535C>T p.R179W | Missense Mutation (SNP) | VAF 298/458 reads (65%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as rs1446417106; called by muse, varscan2
- GRAMD4 | c.323A>G p.E108G | Missense Mutation (SNP) | VAF 118/377 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as rs1355344248; called by muse, mutect2, varscan2
- GRIA4 | c.1881G>A p.W627* | Nonsense Mutation (SNP) | VAF 94/268 reads (35%) | catalogued as COSV56900025; called by muse, mutect2, varscan2
- GRIK5 | c.157G>A p.G53R | Missense Mutation (SNP) | VAF 176/546 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs946029446, COSV53479788; called by muse, mutect2, varscan2
- H2BC8 | c.148C>T p.H50Y | Missense Mutation (SNP) | VAF 116/266 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as COSV55126798; called by muse, mutect2, varscan2
- H4C2 | c.47C>G p.A16G | Missense Mutation (SNP) | VAF 111/241 reads (46%) | SIFT deleterious (0); catalogued as rs768892611; called by muse, mutect2, varscan2
- HDAC4 | c.2423C>A p.T808K | Missense Mutation (SNP) | VAF 211/588 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV100614458; called by muse, mutect2, varscan2
- HEATR6 | c.1358T>G p.L453R | Missense Mutation (SNP) | VAF 110/397 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.5); catalogued as rs758655598; called by muse, mutect2, varscan2
- HNRNPCL1 | c.724G>T p.G242W | Missense Mutation (SNP) | VAF 402/613 reads (66%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs537856884, COSV58611968; called by muse, mutect2, varscan2
- HPS5 | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 72/153 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.132); catalogued as rs201664625; called by muse, mutect2, varscan2
- IFT172 | c.2752G>A p.V918M | Missense Mutation (SNP) | VAF 223/347 reads (64%) | SIFT deleterious (0.05); PolyPhen benign (0.021); catalogued as rs756120365; called by muse, mutect2, varscan2
- INSRR | c.3413G>A p.R1138Q | Missense Mutation (SNP) | VAF 210/411 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs765835617, COSV63875965; called by muse, mutect2, varscan2
- JAK1 | c.3004C>T p.R1002W | Missense Mutation (SNP) | VAF 124/376 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53806640, COSV99605223; called by muse, mutect2, varscan2
- KMT2D | c.3370C>T p.P1124S | Missense Mutation (SNP) | VAF 145/319 reads (45%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.01); catalogued as rs772239870; called by muse, mutect2, varscan2
- LHX5 | c.19G>A p.G7S | Missense Mutation (SNP) | VAF 352/525 reads (67%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.874); catalogued as rs1379830877; called by muse, mutect2, varscan2
- MARK1 | c.1642C>T p.R548* | Nonsense Mutation (SNP) | VAF 246/454 reads (54%) | catalogued as rs1346347772, COSV65068250; called by muse, mutect2, varscan2
- MEI1 | c.3668T>G p.L1223R | Missense Mutation (SNP) | VAF 133/369 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV55387814; called by muse, mutect2, varscan2
- METTL3 | c.484G>T p.E162* | Nonsense Mutation (SNP) | VAF 138/433 reads (32%) | catalogued as COSV99398763; called by muse, mutect2, varscan2
- MEX3D | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 306/414 reads (74%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as rs1423267854; called by muse, varscan2
- MN1 | c.1067C>T p.P356L | Missense Mutation (SNP) | VAF 243/857 reads (28%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.042); catalogued as COSV56563351; called by muse, mutect2, varscan2
- MTUS2 | c.2192A>C p.K731T | Missense Mutation (SNP) | VAF 54/113 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.799); catalogued as COSV70918043, COSV70919467, COSV70920728; called by muse, mutect2, varscan2
- MUC16 | c.41971C>T p.R13991W | Missense Mutation (SNP) | VAF 127/363 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as rs201153547, COSV99063485; called by muse, mutect2, varscan2
- NELL1 | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 109/206 reads (53%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.558); catalogued as rs908099186, COSV54262173; called by muse, mutect2, varscan2
- NPTX2 | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 116/356 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1483768781; called by muse, mutect2, varscan2
- OR1C1 | c.694C>A p.Q232K | Missense Mutation (SNP) | VAF 22/510 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV101376209; called by muse, mutect2
- OR6C2 | c.649T>G p.L217V | Missense Mutation (SNP) | VAF 81/313 reads (26%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.001); catalogued as COSV59515470; called by muse, mutect2, varscan2
- PCDH1 | c.1534G>T p.E512* | Nonsense Mutation (SNP) | VAF 419/425 reads (99%) | catalogued as rs746403208; called by muse, mutect2, varscan2
- PECR | c.605G>T p.G202V | Missense Mutation (SNP) | VAF 53/164 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs141598677, COSV54735514; called by muse, mutect2, varscan2
- PGM3 | c.948T>C p.I316= | Splice Region (SNP) | VAF 72/232 reads (31%) | catalogued as rs1236144153; called by muse, mutect2, varscan2
- POMC | c.274A>G p.S92G | Missense Mutation (SNP) | VAF 231/713 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1197211855; called by muse, mutect2, varscan2
- RBMXL3 | c.2824C>T p.R942C | Missense Mutation (SNP) | VAF 265/748 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.876); catalogued as rs966430682, COSV57749727; called by muse, mutect2, varscan2
- RGS12 | c.3526A>G p.K1176E | Missense Mutation (SNP) | VAF 78/176 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as rs760916479, COSV58750063; called by muse, mutect2, varscan2
- ROS1 | c.4814A>C p.E1605A | Missense Mutation (SNP) | VAF 93/215 reads (43%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as COSV63853576; called by muse, mutect2, varscan2
- SDK1 | c.4487G>A p.R1496Q | Missense Mutation (SNP) | VAF 205/942 reads (22%) | SIFT tolerated (0.61); PolyPhen benign (0.011); catalogued as rs141114121; called by muse, mutect2, varscan2
- SELP | c.2234A>G p.Q745R | Missense Mutation (SNP) | VAF 321/614 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99741201; called by muse, mutect2
- SENP7 | c.3068G>A p.R1023H | Missense Mutation (SNP) | VAF 69/318 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750570862, COSV58607948; called by muse, mutect2, varscan2
- SERPING1 | c.335A>G p.D112G | Missense Mutation (SNP) | VAF 163/338 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.026); catalogued as rs1407130108; called by muse, mutect2, varscan2
- SLC25A37 | c.248A>G p.Q83R | Missense Mutation (SNP) | VAF 106/330 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs909652062; called by muse, mutect2, varscan2
- SORCS1 | c.3445A>G p.R1149G | Missense Mutation (SNP) | VAF 80/267 reads (30%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs755996376; called by muse, mutect2, varscan2
- TCF15 | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 168/266 reads (63%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV55721200; called by muse, mutect2, varscan2
- TCTN1 | c.438T>G p.I146M | Missense Mutation (SNP) | VAF 67/236 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as rs370390020; called by muse, mutect2, varscan2
- TDRD15 | c.946C>G p.P316A | Missense Mutation (SNP) | VAF 95/340 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as rs1489812967; called by muse, mutect2, varscan2
- THAP4 | c.1729C>G p.P577A | Missense Mutation (SNP) | VAF 91/275 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV100398287; called by muse, mutect2, varscan2
- TIAM1 | c.2845G>A p.D949N | Missense Mutation (SNP) | VAF 208/425 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs576007084; called by muse, mutect2, varscan2
- TMEM147 | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 115/331 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1355089168, COSV99383326; called by muse, mutect2, varscan2
- TP53 | c.902dup p.G302Rfs*4 | Frame Shift Ins (INS) | VAF 272/382 reads (71%) | catalogued as COSV53177081; called by mutect2, pindel, varscan2
- UTS2R | c.164G>A p.G55E | Missense Mutation (SNP) | VAF 242/727 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1484378172; called by muse, mutect2, varscan2
- WNT10B | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 171/358 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.227); catalogued as rs749553356; called by muse, varscan2
- ZC3H7B | c.538T>G p.F180V | Missense Mutation (SNP) | VAF 104/336 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0.022); catalogued as COSV60965045; called by muse, mutect2, varscan2
- ZDHHC1 | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 45/359 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775156668; called by muse, mutect2, varscan2
- ZNF2 | c.986A>C p.N329T (on ENST00000611147 / NM_001291605.2; = p.N316T on NM_021088.4) | Missense Mutation (SNP) | VAF 107/305 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV99728317; called by muse, mutect2, varscan2
- ZNF362 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 161/509 reads (32%) | SIFT tolerated (0.71); PolyPhen benign (0.085); catalogued as COSV65031980; called by muse, mutect2, varscan2
- ZNF407 | c.3796G>A p.V1266I | Missense Mutation (SNP) | VAF 235/360 reads (65%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs751450561, COSV55259670; called by muse, mutect2, varscan2
- ZNF536 | c.1051G>A p.G351S | Missense Mutation (SNP) | VAF 173/556 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62819589, COSV62820183, COSV62820593; called by muse, mutect2, varscan2
- ZSCAN10 | c.1423G>A p.A475T (on ENST00000252463; = p.A530T on NM_032805.3) | Missense Mutation (SNP) | VAF 285/666 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as rs199734696; called by muse, mutect2, varscan2
- ADAMTSL3 | c.243G>A p.W81* | Nonsense Mutation (SNP) | VAF 119/358 reads (33%) | called by muse, mutect2, varscan2
- ADGRG1 | c.624G>T p.Q208H | Missense Mutation (SNP) | VAF 27/255 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- ALMS1 | c.7889C>A p.S2630Y | Missense Mutation (SNP) | VAF 126/412 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ALX4 | c.22T>C p.S8P | Missense Mutation (SNP) | VAF 127/246 reads (52%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- ANKRD30B | c.3672T>A p.Y1224* | Nonsense Mutation (SNP) | VAF 78/243 reads (32%) | called by muse, mutect2, varscan2
- ARGLU1 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 276/516 reads (53%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP11B | c.71A>C p.K24T | Missense Mutation (SNP) | VAF 140/455 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- ARHGEF17 | c.134G>C p.R45P | Missense Mutation (SNP) | VAF 293/636 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- ARID1A | c.836_846del p.P279Rfs*117 | Frame Shift Del (DEL) | VAF 224/779 reads (29%) | called by mutect2, pindel, varscan2
- ARID1A | c.1657_1658del p.Q553Afs*69 | Frame Shift Del (DEL) | VAF 371/766 reads (48%) | called by pindel, varscan2
- ARIH2 | c.1228C>G p.L410V | Missense Mutation (SNP) | VAF 192/194 reads (99%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- ARPC5 | c.23C>T p.S8L | Missense Mutation (SNP) | VAF 149/584 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- ATP10A | c.2585G>A p.G862E | Missense Mutation (SNP) | VAF 45/266 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ATP11B | c.487T>G p.S163A | Missense Mutation (SNP) | VAF 112/394 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ATP6V1A | c.627G>A p.W209* | Nonsense Mutation (SNP) | VAF 94/404 reads (23%) | called by muse, mutect2, varscan2
- ATP8B1 | c.3245_3249del p.I1082Sfs*33 | Frame Shift Del (DEL) | VAF 135/224 reads (60%) | called by mutect2, pindel, varscan2
- ATP8B1 | c.2192T>C p.L731P | Missense Mutation (SNP) | VAF 68/260 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATR | c.3886A>C p.N1296H | Missense Mutation (SNP) | VAF 87/308 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- BCL9L | c.824A>C p.K275T | Missense Mutation (SNP) | VAF 158/482 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- BCO1 | c.599A>G p.K200R | Missense Mutation (SNP) | VAF 78/218 reads (36%) | SIFT tolerated (0.58); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- BCORL1 | c.4462G>A p.D1488N | Missense Mutation (SNP) | VAF 49/491 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- BIRC2 | c.1104A>C p.E368D | Missense Mutation (SNP) | VAF 76/270 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- BIRC2 | c.1147A>T p.S383C | Missense Mutation (SNP) | VAF 61/187 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BPIFA1 | c.650A>C p.E217A | Missense Mutation (SNP) | VAF 125/396 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- BTAF1 | c.160G>T p.A54S | Missense Mutation (SNP) | VAF 64/213 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- C17orf113 | c.567C>A p.H189Q | Missense Mutation (SNP) | VAF 128/383 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- C6orf15 | c.728A>C p.N243T | Missense Mutation (SNP) | VAF 203/418 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- CACNA1H | c.5026T>G p.F1676V | Missense Mutation (SNP) | VAF 96/246 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.444); called by muse, varscan2
- CAMSAP1 | c.1565C>G p.T522R | Missense Mutation (SNP) | VAF 147/318 reads (46%) | SIFT tolerated (0.37); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CAPN9 | c.1138dup p.I380Nfs*7 | Frame Shift Ins (INS) | VAF 146/364 reads (40%) | called by mutect2, pindel, varscan2
- CASP10 | c.1207G>C p.G403R (on ENST00000272879 / NM_032974.5; = p.G360R on NM_001230.5) | Missense Mutation (SNP) | VAF 310/479 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CASZ1 | c.2874G>T p.M958I | Missense Mutation (SNP) | VAF 151/420 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.047); called by mutect2, varscan2
- CCDC116 | c.1349A>C p.K450T | Missense Mutation (SNP) | VAF 167/505 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCDC27 | c.1004G>T p.G335V | Missense Mutation (SNP) | VAF 179/532 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- CCDC33 | c.914T>C p.L305P | Missense Mutation (SNP) | VAF 140/432 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- CD1E | c.59C>G p.A20G | Missense Mutation (SNP) | VAF 85/326 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDK10 | c.1063A>C p.S355R | Missense Mutation (SNP) | VAF 109/402 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- CELSR1 | c.4336A>T p.S1446C | Missense Mutation (SNP) | VAF 154/570 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CEP250 | c.5280G>C p.Q1760H | Missense Mutation (SNP) | VAF 124/411 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- CEP295 | c.4130T>C p.L1377P | Missense Mutation (SNP) | VAF 129/414 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- CEP57 | c.236A>C p.K79T | Missense Mutation (SNP) | VAF 61/214 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CNTFR | c.191T>C p.L64P | Missense Mutation (SNP) | VAF 161/328 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- COA7 | c.-3_17del | Translation Start Site (DEL) | VAF 131/269 reads (49%) | called by mutect2, pindel, varscan2
- COA8 | c.155G>A p.C52Y | Missense Mutation (SNP) | VAF 103/365 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- COA8 | c.156C>A p.C52* | Nonsense Mutation (SNP) | VAF 106/368 reads (29%) | called by muse, mutect2, varscan2
- COL13A1 | c.479del p.G160Afs*35 | Frame Shift Del (DEL) | VAF 111/459 reads (24%) | called by mutect2, pindel, varscan2
- COL19A1 | c.103C>G p.P35A | Missense Mutation (SNP) | VAF 77/230 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- COL4A1 | c.4096G>T p.G1366C | Missense Mutation (SNP) | VAF 189/194 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL4A5 | c.1306C>A p.P436T | Missense Mutation (SNP) | VAF 224/566 reads (40%) | SIFT tolerated (0.59); PolyPhen benign (0.012); called by mutect2, varscan2
- CPNE1 | c.868G>A p.V290M (on ENST00000352393; = p.V295M on NM_003915.5) | Missense Mutation (SNP) | VAF 109/358 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- CYP2C19 | c.1195A>G p.K399E | Missense Mutation (SNP) | VAF 268/406 reads (66%) | SIFT deleterious (0.02); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- DAG1 | c.2423A>T p.K808M | Missense Mutation (SNP) | VAF 210/377 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DDR2 | c.1233C>G p.I411M | Missense Mutation (SNP) | VAF 95/364 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- DDX3X | c.843dup p.Y282Lfs*12 (on ENST00000399959; = p.Y283Lfs*12 on NM_001356.5) | Frame Shift Ins (INS) | VAF 118/270 reads (44%) | called by mutect2, pindel, varscan2
- DHX8 | c.2313A>C p.E771D | Missense Mutation (SNP) | VAF 94/299 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- DLG3 | c.1811A>G p.K604R | Missense Mutation (SNP) | VAF 130/323 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- DLL4 | c.470_474dup p.E159Wfs*208 | Frame Shift Ins (INS) | VAF 282/506 reads (56%) | called by mutect2, varscan2
- DMD | c.4583A>C p.Q1528P | Missense Mutation (SNP) | VAF 225/371 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- DOCK11 | c.5474A>T p.E1825V | Missense Mutation (SNP) | VAF 25/232 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- DOCK4 | c.4156A>G p.T1386A | Missense Mutation (SNP) | VAF 48/213 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- EFR3B | c.2102A>G p.Q701R | Missense Mutation (SNP) | VAF 174/575 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2
- EIF4B | c.1619C>A p.T540N | Missense Mutation (SNP) | VAF 159/225 reads (71%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- EIF5B | c.2186T>A p.I729N | Missense Mutation (SNP) | VAF 192/283 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ENC1 | c.494A>G p.Y165C | Missense Mutation (SNP) | VAF 217/218 reads (100%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- ENTPD4 | c.1754del p.L585Rfs*107 | Frame Shift Del (DEL) | VAF 289/585 reads (49%) | called by mutect2, pindel, varscan2
- ETFA | c.544A>G p.S182G | Missense Mutation (SNP) | VAF 76/286 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAAH | c.328G>T p.G110W | Missense Mutation (SNP) | VAF 132/405 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- FAM186B | c.1373A>G p.H458R | Missense Mutation (SNP) | VAF 153/301 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FAM204A | c.501T>G p.I167M | Missense Mutation (SNP) | VAF 86/330 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- FAM227B | c.248T>G p.I83S | Missense Mutation (SNP) | VAF 82/260 reads (32%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM229A | c.19_22del p.P7Gfs*45 | Frame Shift Del (DEL) | VAF 133/505 reads (26%) | called by mutect2, pindel, varscan2
- FAT3 | c.4546G>A p.G1516S | Missense Mutation (SNP) | VAF 271/403 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FBF1 | c.3325G>C p.D1109H (on ENST00000586717; = p.D1124H on NM_001319193.1) | Missense Mutation (SNP) | VAF 92/327 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FKBP9 | c.220_221+10del p.X74_splice | Splice Site (DEL) | VAF 406/453 reads (90%) | called by mutect2, pindel, varscan2
- GABRA3 | c.759G>C p.E253D | Missense Mutation (SNP) | VAF 124/413 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- GBP7 | c.1311A>T p.E437D | Missense Mutation (SNP) | VAF 125/354 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- GCNA | c.82A>G p.S28G | Missense Mutation (SNP) | VAF 78/205 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GIPC3 | c.3841G>T p.V1281F | Missense Mutation (SNP) | VAF 138/580 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.813); called by mutect2, varscan2
- GLI4 | c.215T>G p.F72C | Missense Mutation (SNP) | VAF 66/248 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- GNL1 | c.1099+1del p.X367_splice | Splice Site (DEL) | VAF 145/518 reads (28%) | called by mutect2, pindel, varscan2
- GPANK1 | c.526A>C p.S176R | Missense Mutation (SNP) | VAF 250/863 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- GSK3A | c.169G>A p.G57S | Missense Mutation (SNP) | VAF 299/867 reads (34%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- GSTT2 | c.608A>T p.E203V | Missense Mutation (SNP) | VAF 196/249 reads (79%) | SIFT deleterious (0.05); PolyPhen benign (0.442); called by muse, mutect2, varscan2
- HDAC1 | c.1130C>T p.P377L | Missense Mutation (SNP) | VAF 121/371 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HNRNPH2 | c.598A>G p.K200E | Missense Mutation (SNP) | VAF 68/756 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); called by muse, mutect2
- IGF2R | c.5183C>T p.A1728V | Missense Mutation (SNP) | VAF 98/206 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- IL6R | c.1180C>G p.L394V | Missense Mutation (SNP) | VAF 97/374 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- INF2 | c.1947G>C p.K649N | Missense Mutation (SNP) | VAF 108/385 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- INHBC | c.530G>C p.W177S | Missense Mutation (SNP) | VAF 172/464 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNH8 | c.155T>C p.L52P | Missense Mutation (SNP) | VAF 97/320 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNJ14 | c.530A>G p.D177G | Missense Mutation (SNP) | VAF 211/702 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KIF7 | c.1004A>T p.E335V | Missense Mutation (SNP) | VAF 188/628 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KLHDC8A | c.665A>C p.N222T | Missense Mutation (SNP) | VAF 186/624 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- KLHL41 | c.1562A>C p.K521T | Missense Mutation (SNP) | VAF 76/183 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- KMT2B | c.5431T>A p.S1811T | Missense Mutation (SNP) | VAF 217/326 reads (67%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- KMT2D | c.12790G>A p.G4264R | Missense Mutation (SNP) | VAF 429/438 reads (98%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- KNL1 | c.3740A>G p.N1247S (on ENST00000346991 / NM_170589.5; = p.N1221S on NM_144508.5) | Missense Mutation (SNP) | VAF 94/281 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- KRT9 | c.446T>G p.L149R | Missense Mutation (SNP) | VAF 235/758 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2
- LAMA1 | c.8435C>A p.T2812N | Missense Mutation (SNP) | VAF 140/354 reads (40%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.767); called by mutect2, varscan2
- LAMA5 | c.10165A>G p.S3389G | Missense Mutation (SNP) | VAF 182/545 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- LIX1L | c.896A>G p.E299G | Missense Mutation (SNP) | VAF 171/622 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- LMNB2 | c.653A>C p.E218A | Missense Mutation (SNP) | VAF 140/447 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- LONP2 | c.1459T>G p.F487V | Missense Mutation (SNP) | VAF 39/328 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LONRF3 | c.62del p.L21Wfs*13 | Frame Shift Del (DEL) | VAF 215/887 reads (24%) | called by mutect2, pindel, varscan2
- LRATD2 | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 157/486 reads (32%) | SIFT tolerated (0.72); PolyPhen benign (0.01); called by muse, varscan2
- LRPPRC | c.2984T>C p.L995S | Missense Mutation (SNP) | VAF 84/322 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MANBAL | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 155/261 reads (59%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- MAP3K10 | c.2788A>C p.T930P | Missense Mutation (SNP) | VAF 185/620 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- MARCOL | c.608A>G p.K203R | Missense Mutation (SNP) | VAF 228/344 reads (66%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- MBD5 | c.4396G>A p.D1466N | Missense Mutation (SNP) | VAF 19/276 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MIB2 | c.1625A>C p.K542T | Missense Mutation (SNP) | VAF 223/662 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- MICB | c.908T>C p.L303P | Missense Mutation (SNP) | VAF 124/345 reads (36%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- MLLT10 | c.2681C>A p.A894E (on ENST00000307729 / NM_001195626.3; = p.A910E on NM_004641.3) | Missense Mutation (SNP) | VAF 130/398 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- MOV10 | c.1190T>C p.L397P | Missense Mutation (SNP) | VAF 108/353 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- MRPS16 | c.254A>G p.K85R | Missense Mutation (SNP) | VAF 75/244 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MTMR14 | c.965-1G>C p.X322_splice | Splice Site (SNP) | VAF 87/439 reads (20%) | called by muse, mutect2, varscan2
- MTMR14 | c.1141G>C p.D381H | Missense Mutation (SNP) | VAF 92/477 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, varscan2
- MTUS1 | c.2874_2875del p.Q959Rfs*4 (on ENST00000262102 / NM_001363061.1; = p.Q125Rfs*4 on NM_020749.4) | Frame Shift Del (DEL) | VAF 134/406 reads (33%) | called by pindel, varscan2
- MXRA7 | c.377C>T p.P126L | Missense Mutation (SNP) | VAF 192/584 reads (33%) | PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYCBPAP | c.1597A>G p.T533A | Missense Mutation (SNP) | VAF 104/438 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MYO15B | c.2671C>G p.L891V | Missense Mutation (SNP) | VAF 135/428 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYO5A | c.2042T>G p.L681R | Missense Mutation (SNP) | VAF 115/353 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MYO7B | c.5285T>C p.L1762P | Missense Mutation (SNP) | VAF 177/427 reads (41%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2, varscan2
- NANOS1 | c.436G>C p.E146Q | Missense Mutation (SNP) | VAF 228/720 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- NBPF15 | c.1829G>A p.R610K | Missense Mutation (SNP) | VAF 317/604 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- NCOR2 | c.16C>G p.Q6E | Missense Mutation (SNP) | VAF 122/396 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- NHSL1 | c.3265T>C p.S1089P | Missense Mutation (SNP) | VAF 121/274 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NISCH | c.1039T>G p.L347V | Missense Mutation (SNP) | VAF 141/288 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NMD3 | c.841A>T p.I281F | Missense Mutation (SNP) | VAF 126/332 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- NRROS | c.1658G>T p.R553M | Missense Mutation (SNP) | VAF 112/509 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- ONECUT3 | c.1164C>G p.F388L | Missense Mutation (SNP) | VAF 90/348 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- PACS2 | c.235G>T p.E79* | Nonsense Mutation (SNP) | VAF 220/332 reads (66%) | called by muse, mutect2, varscan2
- PAIP2 | c.380T>G p.I127S | Missense Mutation (SNP) | VAF 201/201 reads (100%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- PCDHA4 | c.2357T>G p.L786R | Missense Mutation (SNP) | VAF 291/293 reads (99%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PCDHB9 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 324/329 reads (98%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDIA3 | c.1057C>G p.L353V | Missense Mutation (SNP) | VAF 129/225 reads (57%) | SIFT tolerated (0.33); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- PITPNM1 | c.830A>T p.E277V | Missense Mutation (SNP) | VAF 228/484 reads (47%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- PLD4 | c.644C>A p.S215Y | Missense Mutation (SNP) | VAF 137/417 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- PLEKHA4 | c.253T>A p.F85I | Missense Mutation (SNP) | VAF 97/298 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PLEKHG4 | c.2077T>C p.C693R | Missense Mutation (SNP) | VAF 58/467 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- PMS2 | c.1600G>C p.D534H | Missense Mutation (SNP) | VAF 464/608 reads (76%) | SIFT tolerated (0.12); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- PPIAL4D | c.427G>T p.E143* | Nonsense Mutation (SNP) | VAF 264/1360 reads (19%) | called by mutect2, varscan2
- PRAMEF1 | c.397C>G p.Q133E | Missense Mutation (SNP) | VAF 135/462 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PRDX1 | c.275A>C p.K92T | Missense Mutation (SNP) | VAF 71/241 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- PRR14L | c.247T>G p.L83V | Missense Mutation (SNP) | VAF 113/435 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- PRRT2 | c.263G>A p.S88N | Missense Mutation (SNP) | VAF 208/487 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- PTPN13 | c.3143A>G p.D1048G | Missense Mutation (SNP) | VAF 71/129 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- RHOD | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 160/341 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- RIMS2 | c.1774A>G p.S592G (on ENST00000666250 / NM_001348490.2; = p.S400G on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 74/208 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ROCK2 | c.578T>G p.F193C | Missense Mutation (SNP) | VAF 130/417 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ROS1 | c.2557C>G p.Q853E | Missense Mutation (SNP) | VAF 69/168 reads (41%) | SIFT tolerated (0.97); PolyPhen benign (0); called by muse, mutect2, varscan2
- RPN2 | c.1881G>A p.K627= | Splice Region (SNP) | VAF 83/303 reads (27%) | called by muse, mutect2, varscan2
- RPS19 | c.118G>C p.A40P | Missense Mutation (SNP) | VAF 90/334 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- RPS6KA1 | c.650A>G p.K217R | Missense Mutation (SNP) | VAF 119/403 reads (30%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- RTEL1 | c.698A>C p.K233T | Missense Mutation (SNP) | VAF 72/227 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- RTKN | c.626G>A p.G209D (on ENST00000272430 / NM_001015055.2; = p.G196D on NM_033046.2) | Missense Mutation (SNP) | VAF 417/634 reads (66%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SCAMP3 | c.305A>C p.K102T | Missense Mutation (SNP) | VAF 154/592 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- SEC23B | c.446A>T p.E149V | Missense Mutation (SNP) | VAF 123/370 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- SELP | c.2233C>A p.Q745K | Missense Mutation (SNP) | VAF 323/616 reads (52%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2
- SETDB1 | c.564G>C p.M188I | Missense Mutation (SNP) | VAF 90/329 reads (27%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- SF3B1 | c.2257C>G p.L753V | Missense Mutation (SNP) | VAF 76/244 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- SGK2 | c.1034A>G p.E345G | Missense Mutation (SNP) | VAF 88/288 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- SH3BP2 | c.1550A>G p.D517G | Missense Mutation (SNP) | VAF 116/238 reads (49%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- SHISA9 | c.1102T>C p.F368L | Missense Mutation (SNP) | VAF 219/530 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- SIM1 | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 125/373 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLBP | c.268A>C p.K90Q | Missense Mutation (SNP) | VAF 95/176 reads (54%) | SIFT tolerated (0.12); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- SLC38A5 | c.70G>C p.E24Q | Missense Mutation (SNP) | VAF 74/708 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.036); called by muse, mutect2
- SLK | c.1099dup p.T367Nfs*4 | Frame Shift Ins (INS) | VAF 83/317 reads (26%) | called by mutect2, pindel, varscan2
- SMC1B | c.788T>G p.V263G | Missense Mutation (SNP) | VAF 106/350 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- SNRNP35 | c.586T>C p.S196P | Missense Mutation (SNP) | VAF 155/482 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- SORCS2 | c.1381dup p.I461Nfs*2 | Frame Shift Ins (INS) | VAF 122/244 reads (50%) | called by mutect2, varscan2
- SPTBN1 | c.6544G>T p.A2182S | Missense Mutation (SNP) | VAF 112/362 reads (31%) | SIFT tolerated (0.81); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPTBN4 | c.529A>T p.R177* | Nonsense Mutation (SNP) | VAF 92/285 reads (32%) | called by muse, mutect2, varscan2
- SRRM2 | c.5372C>T p.S1791F | Missense Mutation (SNP) | VAF 40/347 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SSTR2 | c.758A>C p.K253T | Missense Mutation (SNP) | VAF 129/410 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- TNFAIP8L2 | c.40_42del p.E14del | In Frame Del (DEL) | VAF 155/367 reads (42%) | called by mutect2, pindel, varscan2
- TNFRSF10D | c.690T>A p.F230L | Missense Mutation (SNP) | VAF 107/329 reads (33%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNFRSF11A | c.1159A>G p.S387G | Missense Mutation (SNP) | VAF 98/405 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- TNRC6C | c.3561A>C p.Q1187H | Missense Mutation (SNP) | VAF 93/286 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRAF7 | c.1942G>C p.A648P | Missense Mutation (SNP) | VAF 12/390 reads (3%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); called by muse, mutect2
- TRAK2 | c.326A>T p.Y109F | Missense Mutation (SNP) | VAF 178/295 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- TTN | c.949C>A p.P317T | Missense Mutation (SNP) | VAF 99/318 reads (31%) | PolyPhen benign (0.41); called by muse, mutect2, varscan2
- TUFT1 | c.928C>G p.Q310E | Missense Mutation (SNP) | VAF 51/293 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- USP44 | c.1302A>C p.K434N | Missense Mutation (SNP) | VAF 87/298 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- VWA5B1 | c.526A>G p.T176A | Missense Mutation (SNP) | VAF 148/480 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WWC1 | c.2644T>G p.Y882D | Missense Mutation (SNP) | VAF 176/290 reads (61%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- XPO1 | c.3143A>G p.E1048G | Missense Mutation (SNP) | VAF 111/398 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- ZDBF2 | c.3104_3105del p.K1035Mfs*2 | Frame Shift Del (DEL) | VAF 54/248 reads (22%) | called by mutect2, pindel, varscan2
- ZGPAT | c.132_140dup p.L46_I47insMEL | In Frame Ins (INS) | VAF 220/361 reads (61%) | called by mutect2, varscan2
- ZMYM4 | c.3624G>A p.M1208I | Missense Mutation (SNP) | VAF 100/327 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- ZNF559 | c.828A>C p.K276N | Missense Mutation (SNP) | VAF 96/285 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- ZNF682 | c.491del p.N164Tfs*2 | Frame Shift Del (DEL) | VAF 87/311 reads (28%) | called by mutect2, pindel, varscan2
- ZNF713 | c.500T>G p.L167R (on ENST00000633730 / NM_001366796.2; = p.L180R on NM_182633.3) | Missense Mutation (SNP) | VAF 80/854 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.034); called by muse, mutect2
- ZNF75A | c.95C>G p.S32C | Missense Mutation (SNP) | VAF 30/201 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ACACA | c.5343T>G p.P1781= | Silent (SNP) | VAF 106/356 reads (30%) | called by muse, mutect2, varscan2
- ACSBG2 | c.1458C>T p.I486= | Silent (SNP) | VAF 246/379 reads (65%) | catalogued as rs752635667, COSV53128109; called by muse, mutect2, varscan2
- AGRN | c.858C>T p.G286= | Silent (SNP) | VAF 254/822 reads (31%) | catalogued as rs536194916; called by muse, mutect2, varscan2
- ANTKMT | c.513G>A p.V171= | Silent (SNP) | VAF 63/585 reads (11%) | called by muse, mutect2, varscan2
- AP2M1 | c.1041C>T p.S347= | Silent (SNP) | VAF 76/433 reads (18%) | catalogued as rs770699298; called by muse, mutect2, varscan2
- APLP1 | c.1249C>T p.L417= | Silent (SNP) | VAF 154/471 reads (33%) | catalogued as COSV55706678; called by muse, mutect2, varscan2
- ARMC5 | c.1764C>G p.G588= | Silent (SNP) | VAF 259/544 reads (48%) | catalogued as COSV51654674; called by muse, mutect2, varscan2
- B4GALNT1 | c.1083C>T p.F361= | Silent (SNP) | VAF 199/541 reads (37%) | called by muse, mutect2, varscan2
- BCOR | c.2109C>G p.P703= | Silent (SNP) | VAF 219/754 reads (29%) | called by muse, mutect2, varscan2
- C4BPA | c.351A>T p.G117= | Silent (SNP) | VAF 68/228 reads (30%) | called by muse, mutect2, varscan2
- C8B | c.1275C>A p.V425= | Silent (SNP) | VAF 138/422 reads (33%) | catalogued as COSV100980837; called by muse, mutect2, varscan2
- CACUL1 | c.300G>A p.V100= | Silent (SNP) | VAF 195/578 reads (34%) | called by muse, mutect2, varscan2
- CBLL2 | c.1272G>A p.R424= | Silent (SNP) | VAF 80/319 reads (25%) | called by muse, varscan2
- CDC20B | c.226A>C p.R76= | Silent (SNP) | VAF 144/570 reads (25%) | catalogued as COSV57052783, COSV57054933; called by muse, mutect2, varscan2
- CDK12 | c.927G>A p.R309= | Silent (SNP) | VAF 175/572 reads (31%) | called by muse, mutect2, varscan2
- CDR2 | c.846T>C p.P282= | Silent (SNP) | VAF 147/326 reads (45%) | catalogued as rs1255177044; called by muse, mutect2, varscan2
- CLCA2 | c.891A>C p.P297= | Silent (SNP) | VAF 102/332 reads (31%) | called by muse, mutect2, varscan2
- CSF2RB | c.984A>G p.A328= | Silent (SNP) | VAF 150/498 reads (30%) | called by muse, mutect2, varscan2
- CSPG5 | c.1048T>C p.L350= | Silent (SNP) | VAF 176/338 reads (52%) | catalogued as rs1321154597; called by muse, mutect2, varscan2
- CYC1 | c.105G>C p.G35= | Silent (SNP) | VAF 100/376 reads (27%) | catalogued as COSV59645208; called by muse, mutect2, varscan2
- DHX16 | c.852G>C p.R284= | Silent (SNP) | VAF 220/787 reads (28%) | catalogued as rs1244094588; called by muse, mutect2, varscan2
- EEF1G | c.961C>T p.L321= | Silent (SNP) | VAF 110/249 reads (44%) | called by muse, mutect2, varscan2
- FCER1G | c.225T>G p.T75= | Silent (SNP) | VAF 127/519 reads (24%) | called by muse, mutect2, varscan2
- FLNC | c.3807G>A p.V1269= | Silent (SNP) | VAF 113/323 reads (35%) | catalogued as COSV57954502; called by muse, mutect2, varscan2
- FREM3 | c.651C>T p.D217= | Silent (SNP) | VAF 180/416 reads (43%) | called by muse, mutect2, varscan2
- GFRA4 | c.231C>T p.P77= | Silent (SNP) | VAF 261/763 reads (34%) | catalogued as rs943616306; called by muse, mutect2, varscan2
- HAMP | c.30T>C p.A10= | Silent (SNP) | VAF 105/359 reads (29%) | called by muse, varscan2
- HAUS4 | c.93A>G p.K31= | Silent (SNP) | VAF 106/380 reads (28%) | called by muse, mutect2, varscan2
- HHIP | c.733C>T p.L245= | Silent (SNP) | VAF 120/262 reads (46%) | called by muse, mutect2, varscan2
- HSPA8 | c.1446C>T p.A482= | Silent (SNP) | VAF 165/280 reads (59%) | catalogued as rs1464591027; called by muse, mutect2, varscan2
- HSPG2 | c.3990C>A p.I1330= | Silent (SNP) | VAF 163/539 reads (30%) | catalogued as COSV101020463; called by muse, mutect2, varscan2
- IGHV4-39 | c.135C>A p.S45= | Silent (SNP) | VAF 28/373 reads (8%) | catalogued as rs768814749; called by muse, mutect2
- ITGB3 | c.1398A>G p.Q466= | Silent (SNP) | VAF 145/442 reads (33%) | catalogued as rs1157304490; called by muse, mutect2, varscan2
- KLHL35 | c.405G>A p.V135= | Silent (SNP) | VAF 50/514 reads (10%) | called by muse, mutect2, varscan2
- KMT2A | c.9507T>C p.T3169= | Silent (SNP) | VAF 134/433 reads (31%) | called by muse, mutect2, varscan2
- LIPI | c.1005G>A p.R335= | Silent (SNP) | VAF 103/200 reads (52%) | called by muse, mutect2, varscan2
- MBD5 | c.2896C>T p.L966= | Silent (SNP) | VAF 214/358 reads (60%) | catalogued as COSV68698136; called by muse, mutect2, varscan2
- MDN1 | c.2695A>C p.R899= | Silent (SNP) | VAF 108/332 reads (33%) | called by muse, mutect2, varscan2
- MIB2 | c.969C>G p.T323= | Silent (SNP) | VAF 221/720 reads (31%) | called by muse, mutect2, varscan2
- MROH1 | c.2412C>T p.C804= | Silent (SNP) | VAF 136/412 reads (33%) | called by muse, mutect2, varscan2
- MRPS10 | c.531A>G p.L177= | Silent (SNP) | VAF 79/286 reads (28%) | called by muse, mutect2, varscan2
- NETO1 | c.531C>T p.G177= | Silent (SNP) | VAF 185/288 reads (64%) | catalogued as rs139115866; called by muse, mutect2, varscan2
- NMB | c.27G>T p.R9= | Silent (SNP) | VAF 400/565 reads (71%) | called by muse, mutect2, varscan2
- NODAL | c.444G>A p.L148= | Silent (SNP) | VAF 127/388 reads (33%) | called by muse, mutect2, varscan2
- NTN1 | c.1626C>A p.I542= | Silent (SNP) | VAF 120/426 reads (28%) | catalogued as COSV99431976; called by muse, mutect2, varscan2
- NUTM2B | c.1689G>C p.L563= | Silent (SNP) | VAF 48/394 reads (12%) | called by muse, mutect2, varscan2
- OR5H8 | c.15T>C p.N5= | Silent (SNP) | VAF 37/252 reads (15%) | catalogued as rs1559852179; called by muse, mutect2, varscan2
- OTOG | c.5466G>C p.L1822= | Silent (SNP) | VAF 231/465 reads (50%) | called by muse, mutect2, varscan2
- PAPSS1 | c.921T>G p.P307= | Silent (SNP) | VAF 95/202 reads (47%) | called by muse, mutect2, varscan2
- PCNX3 | c.1674G>C p.G558= | Silent (SNP) | VAF 149/296 reads (50%) | called by muse, mutect2, varscan2
- PIKFYVE | c.5145T>A p.P1715= | Silent (SNP) | VAF 14/268 reads (5%) | called by muse, mutect2
- PIWIL2 | c.2157T>C p.L719= | Silent (SNP) | VAF 117/282 reads (41%) | called by muse, mutect2, varscan2
- PLEC | c.3279C>G p.R1093= (on ENST00000322810 / NM_201380.4; = p.R983= on NM_000445.5) | Silent (SNP) | VAF 155/463 reads (33%) | catalogued as rs782055973; called by muse, mutect2, varscan2
- PLIN4 | c.927G>A p.V309= (on ENST00000301286; = p.V324= on NM_001367868.2) | Silent (SNP) | VAF 94/316 reads (30%) | called by muse, mutect2, varscan2
- PLIN4 | c.828G>A p.V276= (on ENST00000301286; = p.V291= on NM_001367868.2) | Silent (SNP) | VAF 105/325 reads (32%) | called by muse, mutect2, varscan2
- POU5F2 | c.246T>A p.R82= | Silent (SNP) | VAF 616/621 reads (99%) | called by muse, mutect2, varscan2
- PPFIA1 | c.2736G>A p.S912= | Silent (SNP) | VAF 134/287 reads (47%) | catalogued as rs993610403, COSV99557541; called by muse, mutect2, varscan2
- PPIAL4D | c.426G>A p.T142= | Silent (SNP) | VAF 291/1479 reads (20%) | catalogued as rs1264145989; called by muse, mutect2, varscan2
- PTPRF | c.132G>C p.G44= | Silent (SNP) | VAF 137/395 reads (35%) | called by muse, mutect2, varscan2
- PTPRO | c.597T>G p.T199= | Silent (SNP) | VAF 98/204 reads (48%) | called by muse, mutect2, varscan2
- RAP1GDS1 | c.1653C>T p.I551= | Silent (SNP) | VAF 79/177 reads (45%) | called by muse, mutect2, varscan2
- RB1CC1 | c.672T>G p.P224= | Silent (SNP) | VAF 129/229 reads (56%) | called by muse, mutect2, varscan2
- RIMBP3 | c.3036C>G p.T1012= | Silent (SNP) | VAF 255/1016 reads (25%) | called by muse, mutect2, varscan2
- RNFT2 | c.306C>T p.G102= | Silent (SNP) | VAF 425/638 reads (67%) | called by muse, mutect2, varscan2
- RNPEP | c.324G>C p.V108= | Silent (SNP) | VAF 238/907 reads (26%) | called by muse, mutect2, varscan2
- RPL8 | c.753T>A p.T251= | Silent (SNP) | VAF 186/292 reads (64%) | called by muse, mutect2, varscan2
- RTKN | c.1017C>A p.L339= (on ENST00000272430 / NM_001015055.2; = p.L326= on NM_033046.2) | Silent (SNP) | VAF 242/344 reads (70%) | called by muse, mutect2, varscan2
- SALL2 | c.2793G>A p.K931= | Silent (SNP) | VAF 40/634 reads (6%) | called by muse, mutect2
- SERTM1 | c.18T>C p.T6= | Silent (SNP) | VAF 102/211 reads (48%) | called by muse, mutect2, varscan2
- SF3B4 | c.219C>A p.I73= | Silent (SNP) | VAF 113/401 reads (28%) | catalogued as rs782544906; called by muse, mutect2, varscan2
- SFRP2 | c.705G>A p.S235= | Silent (SNP) | VAF 147/345 reads (43%) | catalogued as rs143701440; called by muse, mutect2, varscan2
- SH3TC1 | c.198T>A p.A66= | Silent (SNP) | VAF 193/394 reads (49%) | called by muse, mutect2, varscan2
- SHC2 | c.789C>T p.Y263= | Silent (SNP) | VAF 158/462 reads (34%) | catalogued as rs760036602; called by muse, mutect2, varscan2
- SHROOM2 | c.3270C>T p.L1090= | Silent (SNP) | VAF 347/980 reads (35%) | catalogued as rs765486446; called by muse, mutect2, varscan2
- SMO | c.1791C>T p.D597= | Silent (SNP) | VAF 38/240 reads (16%) | catalogued as rs150159670; called by muse, mutect2, varscan2
- SMPX | c.213G>A p.S71= | Silent (SNP) | VAF 143/412 reads (35%) | catalogued as rs375602080, COSV65278359; called by muse, mutect2, varscan2
- SPAG17 | c.6618A>C p.T2206= | Silent (SNP) | VAF 81/337 reads (24%) | catalogued as COSV60468818; called by muse, mutect2, varscan2
- SUN1 | c.246C>G p.S82= (on ENST00000405266 / NM_001367651.1; = p.S32= on NM_025154.6 and 13 other RefSeq transcripts) | Silent (SNP) | VAF 134/573 reads (23%) | catalogued as COSV100568789; called by muse, mutect2, varscan2
- TBX21 | c.1362G>A p.L454= | Silent (SNP) | VAF 421/645 reads (65%) | called by muse, mutect2, varscan2
- TDRD5 | c.1848T>G p.G616= | Silent (SNP) | VAF 76/433 reads (18%) | called by muse, mutect2, varscan2
- TENM3 | c.5265A>G p.Q1755= | Silent (SNP) | VAF 114/244 reads (47%) | catalogued as COSV69300149; called by muse, mutect2, varscan2
- THSD4 | c.189G>A p.S63= | Silent (SNP) | VAF 230/690 reads (33%) | called by muse, mutect2, varscan2
- TLE3 | c.972C>T p.N324= | Silent (SNP) | VAF 124/450 reads (28%) | catalogued as rs369412380; called by muse, mutect2, varscan2
- TPTE | c.771G>A p.Q257= (on ENST00000618007 / NM_199261.4; = p.Q239= on NM_199259.4) | Silent (SNP) | VAF 51/368 reads (14%) | catalogued as rs947389703; called by muse, mutect2, varscan2
- UBR4 | c.3714C>T p.T1238= | Silent (SNP) | VAF 176/276 reads (64%) | called by muse, mutect2, varscan2
- URI1 | c.1116C>T p.S372= | Silent (SNP) | VAF 102/352 reads (29%) | called by muse, mutect2, varscan2
- VN1R5 | c.336T>C p.T112= | Silent (SNP) | VAF 82/346 reads (24%) | called by muse, mutect2, varscan2
- VPS13C | c.9052A>C p.R3018= (on ENST00000644861 / NM_020821.3; = p.R2975= on NM_017684.5) | Silent (SNP) | VAF 148/262 reads (56%) | called by muse, mutect2, varscan2
- WNK1 | c.5811T>C p.T1937= (on ENST00000315939 / NM_018979.4; = p.T1689= on NM_014823.3) | Silent (SNP) | VAF 132/282 reads (47%) | called by muse, mutect2, varscan2
- ZFYVE26 | c.1149C>T p.A383= | Silent (SNP) | VAF 128/362 reads (35%) | catalogued as COSV100720051; called by muse, mutect2, varscan2
- ZNF221 | c.33A>G p.S11= | Silent (SNP) | VAF 96/302 reads (32%) | called by muse, mutect2, varscan2
- ZNF467 | c.1008T>G p.A336= | Silent (SNP) | VAF 193/537 reads (36%) | called by muse, mutect2, varscan2
- ZNF770 | c.1233T>A p.S411= | Silent (SNP) | VAF 101/310 reads (33%) | called by muse, mutect2, varscan2
- ZNF776 | c.459G>A p.K153= | Silent (SNP) | VAF 286/444 reads (64%) | called by muse, mutect2, varscan2
- ZZEF1 | c.549G>T p.S183= | Silent (SNP) | VAF 137/137 reads (100%) | catalogued as rs149589527; called by muse, mutect2, varscan2
- CUTA | c.-94C>G | 5'UTR (SNP) | VAF 218/956 reads (23%) | called by muse, mutect2
- DST | c.4297-1835A>G | Intron (SNP) | VAF 225/338 reads (67%) | called by muse, mutect2, varscan2
- GPR35 | c.-45G>T | 5'UTR (SNP) | VAF 103/320 reads (32%) | called by muse, mutect2, varscan2
- ITGA2 | c.*249C>G | 3'UTR (SNP) | VAF 31/147 reads (21%) | called by muse, mutect2, varscan2
- LONP2 | chr16:48361706 T>C | 3'Flank (SNP) | VAF 227/261 reads (87%) | called by muse, mutect2, varscan2
- NMNAT3 | c.110-20350A>C | Intron (SNP) | VAF 49/403 reads (12%) | called by muse, mutect2, varscan2
- PCSK6 | c.1859-14820G>A | Intron (SNP) | VAF 69/275 reads (25%) | called by muse, mutect2, varscan2
- PCSK6 | c.1858+1158T>C | Intron (SNP) | VAF 94/312 reads (30%) | called by muse, mutect2, varscan2
- PDZD7 | chr10:101016420 G>A | 3'Flank (SNP) | VAF 194/333 reads (58%) | catalogued as rs751402496, COSV64647037; called by muse, varscan2
- PLEKHA6 | c.382-18C>T | Intron (SNP) | VAF 207/774 reads (27%) | catalogued as rs1185008526; called by muse, mutect2, varscan2
- PSMG4 | chr6:3255085 A>C | 5'Flank (SNP) | VAF 90/90 reads (100%) | catalogued as rs982606623; called by muse, mutect2, varscan2
- REXO1L1P | n.1404T>A | RNA (SNP) | VAF 53/1345 reads (4%) | called by muse, mutect2
- TTN | c.10361-5583G>C | Intron (SNP) | VAF 121/351 reads (34%) | catalogued as rs777193968; called by muse, mutect2, varscan2
